Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1YW, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1YW-06A (Metastatic).

Prof.Dr.

ICD-0-3

Melanoma, NOS 8720/3

Site: Lymph Node, NOS 877-9

hw 7/24/11

Patient: Xxxx
geb. **** *

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 95 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo ratio. The mitotic count is 4 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern with dysshaesive areals. There is no evidence of necrotic tissue. The tumor harbours approx. 0 percent of necrotic tissue.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

Site - CCLF stained Lymph node

Diagnostic Discrepancy		
Primary Tumor Site Discrepancy	NOT STATED	in path
HPVAA Discrepancy		
Quel/S, nchronous Primary Malignancy		

Source: NCI Genomic Data Commons file a4a16b4a-76d8-42ac-a440-6cd287367aaf (TCGA-FS-A1YW.E3BF4EA9-D93C-4469-88E1-D78F18EA4C13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).